Somatic mutation profile of tumor specimen TARGET-10-PAPZTD-09A (aliquot TARGET-10-PAPZTD-09A-01D) from TARGET case TARGET-10-PAPZTD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (3,010 days).
Specimen TARGET-10-PAPZTD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2599de93-9c0c-4158-b278-1cd1d06c4b2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZTD-10A (Blood Derived Normal), aliquot TARGET-10-PAPZTD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7b6267-29c1-458a-a3f2-07b74dd30dc0

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAX5 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM1514451, COSV63906029; called by muse, mutect2
- PCDH1 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.645); catalogued as rs752293984, COSV54617783; called by muse, mutect2, varscan2
- H4C3 | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- IKZF1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB1 | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF404 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- RIMS2 | c.698+53024T>C | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
